Somatic mutation profile of tumor specimen TCGA-DW-5561-01A (aliquot TCGA-DW-5561-01A-01D-1589-08) from TCGA case TCGA-DW-5561, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 51.3 years (18,744 days).
Specimen TCGA-DW-5561-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f620ebf-c4e5-4315-8d1a-6db300ebbb0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DW-5561-10A (Blood Derived Normal), aliquot TCGA-DW-5561-10A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a30786f-2ebb-466f-a3b9-e6fd63189f68

The open-access MAF lists 39 somatic variants for this specimen: 33 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 5, Frame Shift Del 4, Nonsense Mutation 2, In Frame Del 1, Splice Region 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY2 | c.3016G>A p.V1006M | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57868427; called by muse, mutect2, varscan2
- ADCY9 | c.98A>C p.N33T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); catalogued as COSV53574211; called by muse, mutect2, varscan2
- ANAPC4 | c.947A>G p.E316G | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV59543735; called by muse, mutect2, varscan2
- ATG7 | c.658T>A p.F220I | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV61612051; called by muse, mutect2, varscan2
- ATP13A4 | c.2864C>G p.P955R | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs1372506945, COSV61319177; called by muse, mutect2, varscan2
- CDKN2B | c.159C>T p.V53= | Splice Region (SNP) | VAF 8/20 reads (40%) | catalogued as COSV52805198; called by muse, mutect2, varscan2
- CR2 | c.605A>C p.K202T | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as rs893377104, COSV65507215; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ENPEP | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs774784703, COSV54449632; called by muse, mutect2, varscan2
- ETS1 | c.93T>A p.C31* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as COSV60093027; called by muse, mutect2, varscan2
- GALNT4 | c.50T>G p.F17C | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV57964331; called by muse, mutect2, varscan2
- KCND2 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.824); catalogued as COSV58576681; called by muse, mutect2, varscan2
- KIAA1522 | c.2788C>A p.P930T (on ENST00000373480 / NM_001198972.2; = p.P989T on NM_020888.3) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53863821; called by muse, mutect2, varscan2
- MACF1 | c.13054C>G p.P4352A (on ENST00000372915; = p.P2285A on NM_012090.5) | Missense Mutation (SNP) | VAF 18/32 reads (56%) | catalogued as COSV57117628; called by muse, mutect2, varscan2
- NDUFB7 | c.282-1G>T p.X94_splice | Splice Site (SNP) | VAF 29/72 reads (40%) | catalogued as COSV99295221; called by muse, mutect2, varscan2
- OR4A16 | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); catalogued as COSV59042711, COSV59044047; called by muse, mutect2, varscan2
- PRPF4B | c.1868C>G p.S623C | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV61783947; called by muse, mutect2, varscan2
- RBBP5 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV52704055, COSV52706833; called by muse, mutect2, varscan2
- RPS14 | c.26A>G p.K9R | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV56316143; called by muse, mutect2, varscan2
- SEC14L4 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs750590896, COSV55399400; called by muse, mutect2, varscan2
- SLC6A13 | c.1007T>C p.L336P | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751589338, COSV58256695; called by muse, mutect2, varscan2
- SLC7A1 | c.1492A>G p.I498V | Missense Mutation (SNP) | VAF 83/287 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66330270; called by muse, mutect2, varscan2
- SRSF6 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); catalogued as COSV54827425; called by muse, mutect2, varscan2
- SUPT6H | c.434T>C p.I145T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV58926719; called by muse, mutect2, varscan2
- TAS2R20 | c.122T>A p.I41N | Missense Mutation (SNP) | VAF 58/92 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67855079; called by muse, mutect2, varscan2
- TBC1D15 | c.709A>T p.K237* | Nonsense Mutation (SNP) | VAF 47/87 reads (54%) | catalogued as COSV59848766; called by muse, mutect2, varscan2
- TMEM81 | c.698C>A p.A233D | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV52704046; called by muse, mutect2, varscan2
- TRIP4 | c.1033T>C p.Y345H | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs776937263, COSV56030473; called by muse, mutect2, varscan2
- WNK3 | c.1965T>A p.H655Q | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV63613258; called by muse, mutect2, varscan2
- CMBL | c.248_253del p.E83_W85delinsG | In Frame Del (DEL) | VAF 31/100 reads (31%) | called by mutect2, pindel, varscan2
- CPEB4 | c.869del p.S290Ifs*32 | Frame Shift Del (DEL) | VAF 89/270 reads (33%) | called by mutect2, pindel, varscan2
- GAPDH | c.447_454del p.N149Kfs*15 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- OR4K1 | c.488_489del p.T163Sfs*10 | Frame Shift Del (DEL) | VAF 38/108 reads (35%) | called by mutect2, pindel, varscan2
- ZNF681 | c.868_875del p.A290Sfs*9 | Frame Shift Del (DEL) | VAF 36/111 reads (32%) | called by mutect2, pindel, varscan2
- NIPSNAP3B | c.384T>A p.I128= | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as COSV66106547; called by muse, mutect2, varscan2
- PADI3 | c.1989G>A p.V663= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV64934403, COSV64934763; called by muse, mutect2, varscan2
- SPEG | c.4399C>A p.R1467= | Silent (SNP) | VAF 80/143 reads (56%) | catalogued as COSV56667131, COSV56668235; called by muse, mutect2, varscan2
- UBIAD1 | c.924G>C p.L308= | Silent (SNP) | VAF 54/141 reads (38%) | catalogued as COSV65147677; called by muse, mutect2, varscan2
- YWHAH | c.622C>T p.L208= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as rs1417606897, COSV50708304; called by muse, mutect2, varscan2
- C10orf95 | c.-61dup | 5'UTR (INS) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
